Somatic mutation profile of tumor specimen 0DOQGK from CCDI case PBCCIM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,242 days).
Specimen 0DOQGK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf0a70c1-50d6-4f51-a8c1-b0a2e3afaba9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOQGO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b17c2a2a-0aef-4c19-a508-65b72d307b7c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INTS1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 45/742 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); called by muse, mutect2
- GPC1 | c.167-8394G>A | Intron (SNP) | VAF 61/576 reads (11%) | catalogued as rs770940866; called by muse, varscan2
